Surgical pathology report (de-identified scan), TCGA case TCGA-NJ-A4YI, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Rush University, specimen TCGA-NJ-A4YI-01A (Primary Tumor).

[page 1 of 8]
Procedure Location:

1CD-0-3

Path: adenocarcinoma, papillary, NOS 8260/3

CQCF: adenocarcinoma, eccrine 8550/3

Site: lung, ^②upper lobe C34.1

hw
10/31/12

PATHOLOGY SURGICAL

Results

[page 2 of 8]
Entry Date

Component Results

PATHOLOGY RESULT:

Department of Pathology

Final

Clinical Data Repository* This report may not match the original report
format

[page 3 of 8]
FINAL DIAGNOSIS

A. (Level 11 lymph node; excision): Lymphoid tissue positive for metastatic adenocarcinoma.

B. (Right upper lobectomy): Moderately differentiated adenocarcinoma, with foci of papillary differentiation, measuring 3.5 cm in greatest dimension, extending to the pleura. Bronchial, vascular and surgical margins free of tumor. Two of two peribronchial lymph nodes positive for metastatic adenocarcinoma.

pT2N2Mx.

Remainder of lung with mild emphysema.

C. (Level 11 lymph node; excision): One benign lymph node.

D. (Level 4R; excision): Lymphoid tissue positive for metastatic adenocarcinoma.

E. (Level 10R lymph node; excision): One lymph node extensively replaced by metastatic adenocarcinoma with extranodal extension.

[page 4 of 8]
INTRAOPERATIVE CONSULTATION

B. (Right upper lobectomy): Adenocarcinoma.

(frozen section B91)

GROSS DESCRIPTION

A. The specimen is labeled level 11 lymph node. Received fresh is a 3.5 x 2.0 x 0.8 cm fragment of brown-red tissue possibly bearing lymph nodes. The entire specimen is submitted in cassettes A1 and A2.

B. The specimen is labeled right upper lobe. Received fresh for frozen section is a 172 gram, 15.3 x 8.5 x 3.6 cm lobectomy specimen with stapled surgical and bronchovascular margins. The pleura (inked blue) shows focal puckering, beneath which on sectioning is a 3.5 x 2.8 x 2.5 cm ill defined light tan firm mass, approaching the pleura, and located 1.1 cm from the bronchial margin of resection. A portion of the mass is submitted for frozen section with the remnant placed in cassette B91. The remainder of the lung is sectioned, and is unremarkable. Additional sections are submitted as follows: B1, bronchial margin; B2, vascular margin; B3, section from stapled margin; B4, peribronchial nodes; B5 through B8, sections from mass; B9, section from uninvolved lung.

[page 5 of 8]
C. The specimen is labeled level 11 lymph node. Received fresh is a 1.2 x 0.7 x 0.5 cm anthracotic lymph node. The specimen is bisected and entirely submitted in cassette C1.

D. The specimen is labeled level 4R. Received fresh is a 2.2 x 1.7 x 0.7 cm aggregate of pink-tan tissue possibly bearing lymph nodes. The specimen is entirely in cassettes D1 and D2.

E. The specimen is labeled level 10R lymph node. Received fresh is a 3.1 x 2.3 x 1.2 cm pink-yellow fragment of fibroadipose tissue. One lymph node is identified. Sections are submitted as follows: E1 through E3 trisected lymph node, E4 remaining fibroadipose tissue.

SPECIMEN(S) RECEIVED

A: LEVEL 11 LYMPH NODE

B: FROZEN:RIGHT UPPER LOBE NEED DIAGNOSIS

C: LEVEL 11 LYMPH NODE

D: LEVEL 4 R

E: LEVEL 10 R LYMPH NODE

[page 6 of 8]
* The above listed tests (if any) were developed and the performance characteristics determined by _____ These tests have not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays.

OPERATIVE INFORMATION

DIAGNOSIS: LUNG MASS; PROCEDURE: BRONCHOSCOPY FLEXIBLE FIBEROPTIC,
THORACOSCOPY VIDEO ASSISTED

INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE

ICD-9(s):

The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Lab and Collection

[page 7 of 8]
PATHOLOGY SURGIC

b and Collection Information

Pathology

Procedure Location:

Dx discrepancy form attached

Diagnostic Discrepancy	☒	
		11/1/12

[page 8 of 8]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Moderately Differentiated Adenocarcinoma with foci of Papillary differentiation	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Acinar.	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Tumor sampling. No papillary subtypes identified in sample.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	—	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator

Signature

Date

Source: NCI Genomic Data Commons file 987b32b9-6019-43c1-82ce-d84b500c28ef (TCGA-NJ-A4YI.DEFC8FAD-A129-40CA-B0CF-E3773377D8A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).